Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A42B, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A42B-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: URETER, LEFT DISTAL, MARGIN, BIOPSY -

- A. INVASIVE HIGH GRADE UROTHELIAL CARCINOMA.
- B. FLAT UROTHELIAL CARCINOMA IN-SITU

PART 2: URINARY BLADDER AND PROSTATE, CYSTOPROSTATECTOMY -

- A. INVASIVE HIGH GRADE PAPILLARY UROTHELIAL CARCINOMA.
- B. THE CARCINOMA INVADES 7.0 CM.
- C. THE CARCINOMA EXTENSIVELY INVADES INTO DETRUSOR MUSCLE AND PERIVESICULAR SOFT TISSUE.
- D. FLAT CARCINOMA IN-SITU IS PRESENT AT THE LEFT URETER MARGIN (SEE PART 5).
- E. ALL OTHER MARGINS ARE NEGATIVE.
- F. EXTENSIVE LYMPHOVASCULAR INVASION IS IDENTIFIED.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. EXTENSIVE TUMOR NECROSIS IS PRESENT.
- I. PATHOLOGICAL STAGE: pT3a N1 MX.
- J. PROSTATE WITH BENIGN PROSTATIC HYPERPLASIA, NEGATIVE FOR CARCINOMA.

PART 3: LYMPH NODES, LEFT PELVIC, EXCISION -

METASTATIC UROTHELIAL CARCINOMA IN ONE OF SIX LYMPH NODES.

PART 4: LYMPH NODES, RIGHT PELVIC, EXCISION -

EIGHT OUT OF EIGHT BENIGN LYMPH NODES.

PART 5: URETER, LEFT, FINAL MARGIN, BIOPSY -

- A. FLAT CARCINOMA IN-SITU.
- B. NO INVASIVE CARCINOMA IS IDENTIFIED.

ICD-0-3

urothelial carcinoma,
papillary 8130/3

PART 6: URETER, RIGHT, FINAL MARGIN, BIOPSY -

- A. BENIGN UROTHELIUM WITH REACTIVE CHANGES.
- B. NEGATIVE FOR DYSPLASIA OR MALIGNANCY.

Site: bladder, wall, lateral

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Left lateral wall
TUMOR SIZE: Greatest dimension: 7 cm
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Papillary, Solid/nodule, Flat
PATHOLOGIC STAGING (pTNM): pT3b
pN1

9-1-12
RD

C67.2

MARGINS:

pMX
Margin(s) involved by carcinoma in situ
Margin(s): LEFT URETER

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Present

DIRECT EXTENSION OF INVASIVE TUMOR: Perivesical fat

ADDITIONAL PATHOLOGIC FINDINGS: Urothelial carcinoma in situ
Urothelial dysplasia (low-grade intraurothelial neoplasia)

Source: NCI Genomic Data Commons file dd6cda40-8637-4881-bc8e-6262fd8b95e2 (TCGA-BT-A42B.ECB8BC78-5051-4B74-B85C-1D89344E8A37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).